CPTAC case C3L-03143 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/78a36c6a-fa58-401a-97e8-b34f6e7d0ada

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Year of birth: 1950; Vital status: Dead; Days to death: 1,025 days (2.8 years); Year of death: 2020; Country of birth: India.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Corpus uteri; Age at diagnosis: 67.2 years (24,543 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: MX; AJCC pathologic T: T3b; AJCC pathologic M: M1; AJCC pathologic stage: Stage IVB; FIGO stage: Stage IVB; Residual disease: RX; Last known disease status: With tumor; Days to last known disease status: 1,025 days (2.8 years); Progression or recurrence: yes; Days to last follow up: 1,018 days (2.8 years); Tumor focality: Multifocal.
   Pathology details: Greatest tumor dimension: 6 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Margin status: Involved.

Follow-up (4 entries)
- Days to follow up: 389 days (1.1 years); Disease response: With Tumor; ECOG performance status: 2.
- Days to follow up: 767 days (2.1 years); Disease response: With Tumor; ECOG performance status: 2.
- Days to follow up: 767 days (2.1 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 585 days (1.6 years); ECOG performance status: 2.
- Days to follow up: 1,018 days (2.8 years); Disease response: With Tumor; ECOG performance status: 2.

Other clinical attributes
- Weight: 75.75 kg; Height: 165.1 cm; BMI: 27.79.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-03143-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 303 mg; Time between excision and freezing: 5 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-03143-21: Section location: Endometrium; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3L-03143-11: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Time between excision and freezing: 5 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-03143-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
